Gene-level copy-number profile of tumor specimen TCGA-61-2612-01A from TCGA case TCGA-61-2612, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 63.2 years (23,074 days).
Specimen TCGA-61-2612-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-OV.84ee91f1-d11b-4c5b-abee-47cd61945bc4.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-61-2612-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 805 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/108a7a3f-cdd1-4452-afb1-0a58fc2135ed

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 1,206; copy number 2: 7,933; copy number 3: 21,177; copy number 4: 16,307; copy number 5: 3,924; copy number 6: 6,820; copy number 7: 913; copy number 8: 680; copy number 9: 240; copy number 10: 90; copy number 11: 229; copy number 13: 299.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-61-2612-01A-01D-1134-01): tumor purity 0.54, ploidy 3.76, whole-genome doublings 2.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 2,451 genes in 13 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:143,343,180–151,459,494, 316 genes, copy number 7 (broad region; genes not listed).
- chr5:167,284,799–168,667,761, 21 genes, copy number 7: TENM2, AC091820.2, AC091820.1, AC008601.1, AC008708.2, AC008708.1, AC008464.1, AC008705.2, AC008705.1, AC011369.1, AC011369.2, CTB-178M22.2, WWC1, RARS1, FBLL1, PANK3, SLC2A3P1, MIR103A1, MIR103B1, RPL10P9, AC011365.1.
- chr5:168,706,567–168,720,884, 1 gene, copy number 7: SLIT3-AS2.
- chr5:174,336,295–181,342,213, 243 genes, copy number 7 (within-gene range 6–7) (broad region; genes not listed).
- chr6:17,092,714–18,674,001, 29 genes, copy number 7: AL138740.1, STMND1, AL136305.1, RBM24, AL034372.1, CAP2, RPL7P26, SUMO2P13, AL138824.1, FAM8A1, NUP153, RNU6-190P, AL138724.1, RNA5SP204, Y_RNA, KIF13A, AL023807.1, NHLRC1, TPMT, KDM1B, DEK, Y_RNA, AL138825.1, RNU6-263P, DDX18P3, IMPDH1P9, RNF144B, MIR548A1HG, MIR548A1.
- chr8:40,369,981–46,698,688, 90 genes, copy number 7–9 (broad region; genes not listed).
- chr8:52,534,037–70,790,371, 283 genes, copy number 7 (broad region; genes not listed).
- chr8:70,780,914–70,781,008, 1 gene, copy number 7: Y_RNA.
- chr8:119,730,774–120,056,201, 9 genes, copy number 7 (within-gene range 6–7): TAF2, AP005717.2, DSCC1, AC021945.1, RN7SL396P, AP005717.1, DEPTOR, RNA5SP277, AC091563.1.
- chr12:66,767–38,207,192, 859 genes, copy number 8–10 (broad region; genes not listed).
- chr18:31,318,160–36,187,448, 93 genes, copy number 9–13 (broad region; genes not listed).
- chr18:36,189,824–36,190,272, 1 gene, copy number 9: AC023043.4.
- chr19:32,824,142–42,740,481, 505 genes, copy number 8–13 (within-gene range 3–13) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 446. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
